Gene-level copy-number profile of tumor specimen ALCH-B1OE-TTP1-A from ALCHEMIST case ALCH-B1OE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,294 days).
Specimen ALCH-B1OE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c232b842-da80-407e-b67c-72b2f550a632.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/f6b2530c-3b41-466f-a370-75a3758c54c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 4,791; copy number 2: 50,428; copy number 3: 3,014; copy number 4: 117; copy number 5: 8; copy number 6: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,796,628, 1 gene: PRAMEF1.
- chr2:176,121,611–176,137,098, 3 genes (within-gene range 0–2): HOXD-AS2, HOXD9, HOXD8.
- chr2:241,734,602–241,768,816, 3 genes (within-gene range 0–2): D2HGDH, AC114730.1, AC114730.2.
- chr4:1,683,420–1,712,344, 2 genes (within-gene range 0–1): Y_RNA, SLBP.
- chr7:55,731,100–55,743,457, 5 genes: Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr7:72,822,894–72,836,701, 2 genes (within-gene range 0–2): RN7SL377P, SBDSP1.
- chr11:31,784,779–31,817,961, 1 gene (within-gene range 0–2): PAX6.
- chr15:68,749,501–68,750,691, 1 gene: CARS1P1.
- chr17:22,090,743–22,439,033, 10 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4.
- chr21:36,698,773–36,749,917, 2 genes: AP000697.1, SIM2.
- chr22:39,994,954–40,043,534, 1 gene (within-gene range 0–1): FAM83F.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,851,551, 2 genes, copy number 6–11: NCF1, GTF2IRD2.
- chr9:137,139,154–137,204,193, 8 genes, copy number 5 (within-gene range 1–5): GRIN1, LRRC26, AL929554.1, MIR3621, TMEM210, ANAPC2, SSNA1, TPRN.
- chr12:12,355,406–12,357,067, 1 gene, copy number 6: LOH12CR2.

Autosomal genes at a single copy (total copy number 1): 4,392. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
